Somatic mutation profile of tumor specimen TCGA-3A-A9IB-01A (aliquot TCGA-3A-A9IB-01A-21D-A397-08) from TCGA case TCGA-3A-A9IB, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,312 days).
Specimen TCGA-3A-A9IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f197da-dd6a-480a-878b-424b90f59270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IB-10A (Blood Derived Normal), aliquot TCGA-3A-A9IB-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/192f3b7a-caf2-450d-bc12-e64c0d513c9c

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Intron 2, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.83_100del p.V28_E33del | In Frame Del (DEL) | VAF 60/295 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/357 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 42/146 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 50/573 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100462530; called by muse, mutect2
- BUB1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 70/440 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV100241500; called by muse, mutect2, varscan2
- CDHR2 | c.1166T>A p.L389H | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99991965; called by muse, mutect2, varscan2
- CNGA3 | c.1155C>G p.F385L | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV55628077, COSV99737187; called by muse, mutect2, varscan2
- EPHX1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs779600683, COSV99689131; called by muse, mutect2, varscan2
- FANCA | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101225046; called by muse, mutect2
- FBN1 | c.7999G>A p.E2667K | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.134); catalogued as rs149062442, CM154864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 152/703 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99796339; called by muse, mutect2, varscan2
- GPR161 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1433752139, COSV99607008; called by muse, mutect2, varscan2
- GRHL2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307516; called by muse, mutect2, varscan2
- LRCH3 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 37/460 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as COSV100605193, COSV100605198; called by muse, mutect2
- LRP1 | c.10037G>A p.C3346Y | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676667; called by muse, mutect2, varscan2
- LTBP1 | c.2477C>T p.S826F (on ENST00000404816 / NM_206943.4; = p.S500F on NM_000627.4) | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1488685111, COSV100617756; called by muse, mutect2
- MYO16 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1186534652, COSV62746705; called by muse, mutect2
- NKD1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs377648064; called by muse, mutect2
- PCDHB7 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 72/677 reads (11%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.005); catalogued as COSV99175175, COSV99177408; called by muse, mutect2, varscan2
- PMFBP1 | c.1887G>C p.K629N (on ENST00000537465; = p.K624N on NM_031293.3) | Missense Mutation (SNP) | VAF 350/1403 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99401305; called by muse, mutect2, varscan2
- RBM38 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs867171824, COSV100654875, COSV61133782; called by muse, mutect2, varscan2
- RPS6KA6 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV53119377; called by muse, mutect2, varscan2
- SCN3A | c.4513C>G p.Q1505E | Missense Mutation (SNP) | VAF 164/1054 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV51802898, COSV99327798; called by muse, mutect2, varscan2
- SLC5A12 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs142065702, COSV54820885; called by muse, mutect2, varscan2
- TAOK1 | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 95/626 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99914484; called by muse, mutect2, varscan2
- TMEM132E | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs1489752978, COSV100396637; called by muse, mutect2, varscan2
- TTK | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1264711807, COSV100036481; called by muse, mutect2, varscan2
- ZNF175 | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99219672; called by muse, mutect2, varscan2
- ZNF528 | c.1229G>C p.G410A | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100846703; called by muse, mutect2, varscan2
- KRTAP10-2 | c.503del p.C168Sfs*178 | Frame Shift Del (DEL) | VAF 56/402 reads (14%) | called by mutect2, varscan2
- RMC1 | c.688_690del p.H230del | In Frame Del (DEL) | VAF 78/279 reads (28%) | called by pindel, varscan2
- TNFRSF10A | c.1031_1053del p.E344Afs*8 | Frame Shift Del (DEL) | VAF 36/436 reads (8%) | called by mutect2, pindel
- AMPD2 | c.2088G>A p.P696= | Silent (SNP) | VAF 140/737 reads (19%) | catalogued as rs368213563, COSV56647900; called by muse, mutect2, varscan2
- DDX43 | c.735C>T p.D245= | Silent (SNP) | VAF 45/234 reads (19%) | catalogued as rs369730596; called by muse, mutect2, varscan2
- DLD | c.663A>C p.A221= | Silent (SNP) | VAF 11/195 reads (6%) | catalogued as COSV99227365; called by muse, mutect2
- DOCK2 | c.3318C>A p.A1106= | Silent (SNP) | VAF 158/988 reads (16%) | catalogued as COSV99914242; called by muse, mutect2, varscan2
- GPAT2 | c.1422T>C p.H474= | Silent (SNP) | VAF 28/824 reads (3%) | catalogued as COSV100853332; called by muse, mutect2
- KRT85 | c.354C>T p.C118= | Silent (SNP) | VAF 143/818 reads (17%) | catalogued as COSV99225503; called by muse, mutect2, varscan2
- LY75 | c.1161G>T p.A387= | Silent (SNP) | VAF 127/769 reads (17%) | catalogued as COSV55105285, COSV99716751; called by muse, mutect2, varscan2
- NUP153 | c.1008G>A p.L336= | Silent (SNP) | VAF 96/498 reads (19%) | catalogued as COSV100020657; called by muse, mutect2, varscan2
- RTN3 | c.81C>T p.G27= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as rs1241912197, COSV100127482; called by muse, mutect2, varscan2
- SLC32A1 | c.528C>T p.D176= | Silent (SNP) | VAF 50/251 reads (20%) | catalogued as rs780997867, COSV54146680; called by muse, mutect2, varscan2
- CPE | c.307+6743G>A | Intron (SNP) | VAF 33/516 reads (6%) | catalogued as rs371636002, COSV101127490; called by muse, mutect2
- SRSF6 | c.257-499G>A | Intron (SNP) | VAF 41/400 reads (10%) | called by muse, mutect2, varscan2
